Gene-level copy-number profile of tumor specimen ALCH-B2V8-TTP1-A from ALCHEMIST case ALCH-B2V8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 44.7 years (16,314 days).
Specimen ALCH-B2V8-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5444cc62-add3-474b-b2a6-b81579d9c3fd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2V8-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/7c88c73d-8295-4d78-9f3c-6f8717f77c55

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 516; copy number 1: 82; copy number 2: 527; copy number 3: 19,869; copy number 4: 16,582; copy number 5: 12,815; copy number 6: 4,872; copy number 7: 897; copy number 8: 2,737; copy number 9: 1; copy number 13: 1; copy number 17: 1; copy number 18: 2.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,639 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:148,290,889–148,519,604, 1 gene, copy number 7 (within-gene range 4–7): LINC01138.
- chr1:148,358,245–156,243,332, 415 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:17,940,503–19,578,606, 16 genes, copy number 7: AC080080.1, RNMTL1P2, AC080080.2, PRPS1L1, HDAC9, MIR1302-6, AC010082.1, RN7SKP266, HDAC9-AS1, NPM1P13, TWIST1, AC003986.2, AC003986.3, AC003986.1, FERD3L, AC007091.1.
- chr8:64,091–43,540,927, 907 genes, copy number 7–8 (broad region; genes not listed).
- chr8:46,549,089–145,066,685, 1,493 genes, copy number 7–8 (broad region; genes not listed).
- chr9:65,189,995–65,285,209, 4 genes, copy number 13–18: BMS1P12, AL512605.1, AL512605.2, FOXD4L5.
- chr12:19,089,151–25,386,241, 90 genes, copy number 8 (broad region; genes not listed).
- chr13:106,489,745–111,344,249, 72 genes, copy number 7–8 (broad region; genes not listed).
- chr13:112,647,044–113,554,590, 31 genes, copy number 8 (within-gene range 4–8): ATP11AUN, AL139384.1, ATP11A, ATP11A-AS1, AL356752.1, MCF2L, AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3, F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2.
- chr17:80,544,819–80,966,371, 2 genes, copy number 7 (within-gene range 5–7): RPTOR, RPL31P7.
- chr17:80,824,170–80,826,900, 1 gene, copy number 7: AC016245.2.
- chr20:87,250–26,251,546, 531 genes, copy number 8 (broad region; genes not listed).
- chr20:30,278,906–31,311,962, 16 genes, copy number 7–8: LINC01597, AL121762.1, AL121762.2, Y_RNA, FAM242A, FRG1BP, MLLT10P1, 5_8S_rRNA, ANKRD20A21P, U6, RNA5SP528, DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3.
- chr20:62,841,005–62,948,475, 6 genes, copy number 7 (within-gene range 5–7): TCFL5, DPH3P1, ARF4P2, DIDO1, AL117379.1, GID8.
- chr20:63,009,383–63,085,071, 1 gene, copy number 7 (within-gene range 4–7): LINC01749.
- chr20:63,038,011–63,891,545, 50 genes, copy number 7: LINC01056, HAR1B, AL096828.4, HAR1A, AL096828.2, AL096828.1, MIR124-3, YTHDF1, AL096828.3, BIRC7, MIR3196, NKAIN4, FLJ16779, ARFGAP1, MIR4326, COL20A1, RNU6-994P, CHRNA4, AL121827.1, KCNQ2, AL353658.1, KCNQ2-AS1, EEF1A2, AL121829.1, PPDPF, PTK6, SRMS, AL121829.2, FNDC11, HELZ2, GMEB2, MHENCR, STMN3, RTEL1, RTEL1-TNFRSF6B, TNFRSF6B, ARFRP1, ZGPAT, AL121845.3, AL121845.4, LIME1, AL121845.2, SLC2A4RG, ZBTB46, AL121845.1, ZBTB46-AS1, C20orf181, AL118506.1, ABHD16B, TPD52L2.
- chr21:43,107,942–43,168,646, 1 gene, copy number 8 (within-gene range 5–8): AP001631.2.
- chr21:43,159,066–43,172,805, 2 genes, copy number 8–9: AP001631.1, CRYAA.

Autosomal genes at a single copy (total copy number 1): 72. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
